Surgical pathology report (de-identified scan), TCGA case TCGA-KM-A7QD, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-A7QD-01C (Primary Tumor).

[page 1 of 2]
Patient Results

Page 1 of 2

Gender: Female	Birth Date:	Admit Date:
Attending:	Admit Protocol:	Age:
		Location:

Surgical Pathology [OrderID:

Final Results

Final

CASE NUMBER:
DIAGNOSIS:

1. Left renal mass, resection: Renal cell carcinoma, chromophobe type. Inked margins of resection free of tumor. No lesions observed in the normal parenchyma.
2. Left renal mass margin, resection: Renal parenchyma, no tumor seen.
3. Fat over left renal mass, resection: Fibrofatty tissue.

CLINICAL INFORMATION: Allocate Order to Protocol: Brief
Clinical History: Left
renal mass Specimen Taken For Protocol: 01 -
Yes

PROCEDURE: Pre-Operative Diagnosis: Left renal mass Post-Operative
Diagnosis:
Same Operative Findings: Unremarkable

SPECIMENS SUBMITTED: 1. KIDNEY, Left renal mass
2. KIDNEY, Left renal mass margin
3. FAT, Over left renal mass

GROSS DESCRIPTION: Received are 3 fresh specimens in the
containers labeled with patient's name, medical record number, and
further specified as:

1. "Left renal mass", is a pink-tan piece of tissue measuring 2.7 x 2.6 x 1.4 cm. The specimen is inked with sterile ink. The specimen is bisected revealing a yellow-tan nodule measuring 1.2 x 1 cm, and approaches to one of the inked sides. As per surgeon, the lateral border of the renal capsule opened in the specimen extraction bag. Therefore, exposed tumor was inked. Approximately 15% of the tissue is procured for procurement was performed by and on In the specimen received matches the above description. The specimen is entirely submitted for permanent processing in white cassettes -1D.
2. "Left renal mass margin". It consists of a yellow-tan tissue fragment measuring 0.2 x 0.1 x 0.1 cm. The specimen is wrapped in lens paper and entirely submitted for permanent processing in white cassette
3. "Fat over left renal mass". It consists of a yellow-tan fatty tissue measuring 0.8 x 0.8 x 0.2 cm. The specimen is entirely submitted for permanent processing in white cassette

ICD-O-3
Carcinoma, renal cell
chromophobe type 801713
Site @ Kidney NOS
C64.9
JA 9/24/13

[page 2 of 2]
Patient Results

Page 2 of 2

Gender: Female	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Location:

Surgical Pathology	Final Results
---------------------------	----------------------

Gross description dictated by

No consultants

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

JobID:

Requested By: i

Do not file in Medical Record

Source: NCI Genomic Data Commons file e3a2192d-8e0d-4c25-a479-5d6c43660bb1 (TCGA-KM-A7QD.179F39CB-E038-4F9A-89C9-25E800706F22.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).